Somatic mutation profile of tumor specimen TCGA-B2-3924-01A (aliquot TCGA-B2-3924-01A-02D-A270-10) from TCGA case TCGA-B2-3924, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 73.5 years (26,846 days).
Specimen TCGA-B2-3924-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc488878-7050-474c-9c86-d530753352c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B2-3924-10A (Blood Derived Normal), aliquot TCGA-B2-3924-10A-01D-1459-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5d010fc-db63-4ca3-9743-084f08ba7963

The open-access MAF lists 84 somatic variants for this specimen: 63 protein-altering or splice-affecting, 21 silent.
By variant classification: Missense Mutation 45, Silent 21, Frame Shift Del 7, Frame Shift Ins 5, Nonsense Mutation 3, Splice Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.194C>A p.S65* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | hotspot (GDC flag); catalogued as rs5030826, CM941362, CM941363, CM941364, COSV56543026, COSV56543035, COSV56543220, COSV56562588; ClinVar: pathogenic; called by muse, mutect2
- ADAMTS15 | c.1937C>T p.T646I | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as rs763095301, COSV54508917; called by muse, mutect2, varscan2
- ATF7IP2 | c.1468A>G p.N490D | Missense Mutation (SNP) | VAF 96/464 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV61094981; called by muse, mutect2, varscan2
- BAZ1B | c.3100C>G p.L1034V | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); catalogued as COSV59991035; called by muse, mutect2, varscan2
- CCDC186 | c.2149G>T p.V717F | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.428); catalogued as COSV65161910; called by muse, mutect2, varscan2
- CEP350 | c.7889G>T p.S2630I | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100854596, COSV62608412; called by muse, mutect2, varscan2
- CHD2 | c.1241T>C p.L414P | Missense Mutation (SNP) | VAF 65/268 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59122114; called by muse, mutect2, varscan2
- CNOT6 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.098); catalogued as COSV56163628; called by muse, mutect2, varscan2
- COL1A2 | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV51964033; called by muse, mutect2, varscan2
- COL2A1 | c.1252G>C p.A418P | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV61533196; called by muse, mutect2, varscan2
- CPNE1 | c.1298A>C p.E433A (on ENST00000352393; = p.E438A on NM_003915.5) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV100467332, COSV58294183; called by muse, mutect2, varscan2
- DENND2C | c.825G>T p.E275D | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67923567; called by muse, mutect2, varscan2
- EMILIN2 | c.1586G>C p.G529A | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as rs1163543152, COSV54426526; called by muse, mutect2, varscan2
- FCGBP | c.10588C>T p.R3530W | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs756014391; called by muse, mutect2
- LRRCC1 | c.2699A>C p.Y900S | Missense Mutation (SNP) | VAF 104/431 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV64485198; called by muse, mutect2, varscan2
- MAN2C1 | c.325G>C p.V109L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV51238119; called by muse, mutect2
- MAPKBP1 | c.1481T>A p.L494Q (on ENST00000456763 / NM_001128608.2; = p.L488Q on NM_014994.3) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52966111; called by muse, mutect2, varscan2
- MDGA1 | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as COSV51800430; called by muse, mutect2, varscan2
- MPZL2 | c.235T>C p.Y79H | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1055724506, COSV54049405; called by muse, mutect2, varscan2
- MYO10 | c.3536A>G p.H1179R | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57027898; called by muse, mutect2, varscan2
- MYO1B | c.1554+1G>T p.X518_splice | Splice Site (SNP) | VAF 9/87 reads (10%) | catalogued as COSV58432437; called by muse, mutect2, varscan2
- NPLOC4 | c.196T>A p.L66M | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.549); catalogued as COSV58618552; called by muse, mutect2, varscan2
- OLFM4 | c.1300T>C p.F434L | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54579361; called by muse, mutect2, varscan2
- PCDH7 | c.2236A>T p.K746* | Nonsense Mutation (SNP) | VAF 30/123 reads (24%) | catalogued as COSV62342546; called by muse, mutect2, varscan2
- PCDHA8 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 36/306 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.986); catalogued as COSV65339632; called by muse, mutect2, varscan2
- PCDHB16 | c.2096C>G p.S699W | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53361594, COSV53368932; called by muse, varscan2
- PGLYRP3 | c.319C>G p.H107D | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51952217; called by muse, mutect2
- PIBF1 | c.1549C>T p.Q517* | Nonsense Mutation (SNP) | VAF 27/84 reads (32%) | catalogued as COSV58327175; called by muse, mutect2, varscan2
- PKHD1 | c.9457T>C p.F3153L | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.44); catalogued as COSV61890470; called by muse, mutect2, varscan2
- PSMA4 | c.148C>A p.R50S | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV50385101; called by muse, mutect2, varscan2
- PTPRG | c.3943del p.Q1315Sfs*12 | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | catalogued as COSV55629580; called by mutect2, pindel, varscan2
- RAD50 | c.3757A>C p.I1253L | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.442); catalogued as COSV54756384; called by muse, mutect2, varscan2
- RALGAPB | c.930A>C p.E310D | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.79); catalogued as COSV53442708; called by muse, mutect2
- RBBP6 | c.4805A>G p.Q1602R | Missense Mutation (SNP) | VAF 44/251 reads (18%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.01); catalogued as COSV60507863; called by muse, mutect2, varscan2
- RNF212 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.639); catalogued as COSV67113748, COSV67114894; called by muse, mutect2, varscan2
- SELP | c.1765C>A p.R589S | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as rs370194750, COSV55256588; called by muse, mutect2, varscan2
- SEPTIN5 | c.370C>G p.P124A | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.421); catalogued as COSV63530508, COSV63530948; called by muse, mutect2, varscan2
- SLC25A48 | c.455C>A p.P152H (on ENST00000650267; = p.P98H on NM_001349335.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.454); catalogued as rs1561551214, COSV50850707; called by muse, mutect2, varscan2
- SLC2A11 | c.1370C>A p.P457H (on ENST00000345044 / NM_001024938.4; = p.P464H on NM_030807.5) | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55391426, COSV55393519; called by muse, mutect2, varscan2
- SLC4A1 | c.2393C>T p.T798M | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.611); catalogued as rs753927017, COSV52262390; called by muse, mutect2, varscan2
- SSH2 | c.1007A>G p.Y336C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV52179165; called by muse, mutect2, varscan2
- SYDE2 | c.2966A>G p.Q989R | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV58325124; called by muse, mutect2, varscan2
- TMLHE | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 72/126 reads (57%) | SIFT tolerated (0.54); PolyPhen benign (0.391); catalogued as COSV57687207; called by muse, mutect2, varscan2
- UACA | c.1989A>C p.E663D | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59858617; called by muse, mutect2, varscan2
- UPF2 | c.3253G>A p.E1085K | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.973); catalogued as COSV62658802; called by muse, mutect2, varscan2
- UPF2 | c.2530C>T p.H844Y | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.701); catalogued as COSV62662920; called by muse, mutect2, varscan2
- VPS35L | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.542); catalogued as COSV51989258; called by muse, mutect2, varscan2
- ZFYVE26 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.309); catalogued as COSV61332469; called by muse, mutect2, varscan2
- ALKBH3 | c.834_837dup p.D280Sfs*14 | Frame Shift Ins (INS) | VAF 9/38 reads (24%) | called by mutect2, pindel, varscan2
- ARID4B | c.146del p.V49Gfs*8 | Frame Shift Del (DEL) | VAF 22/125 reads (18%) | called by mutect2, pindel, varscan2
- ASPHD2 | c.445A>G p.I149V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD2 | c.1058_1060del p.K353del | In Frame Del (DEL) | VAF 13/69 reads (19%) | called by mutect2, pindel, varscan2
- CSNK2B | c.603_604del p.Q202Sfs*43 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- KCNB2 | c.2376del p.K792Nfs*16 | Frame Shift Del (DEL) | VAF 17/81 reads (21%) | called by mutect2, varscan2
- MAP7 | c.352del p.E118Sfs*68 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- MDN1 | c.5051dup p.N1684Kfs*2 | Frame Shift Ins (INS) | VAF 21/114 reads (18%) | called by mutect2, pindel, varscan2
- NAPRT | c.1198G>T p.V400L | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); called by muse, varscan2
- PBRM1 | c.2864del p.N955Tfs*59 (on ENST00000296302 / NM_001366071.2; = p.N955Tfs*53 on NM_018313.5) | Frame Shift Del (DEL) | VAF 39/116 reads (34%) | called by mutect2, pindel, varscan2
- PRR12 | c.755_756del p.L252Qfs*50 (on ENST00000615927; = p.L1073Qfs*50 on NM_020719.3) | Frame Shift Del (DEL) | VAF 25/94 reads (27%) | called by mutect2, pindel, varscan2
- RDH5 | c.830_831insG p.R278Pfs*58 | Frame Shift Ins (INS) | VAF 13/56 reads (23%) | called by mutect2, pindel, varscan2
- SSBP2 | c.135+1_135+10del p.X45_splice | Splice Site (DEL) | VAF 101/614 reads (16%) | called by mutect2, pindel, varscan2
- VIL1 | c.1593dup p.E532* | Frame Shift Ins (INS) | VAF 18/86 reads (21%) | called by mutect2, pindel, varscan2
- ZNF382 | c.1218dup p.P407Tfs*5 | Frame Shift Ins (INS) | VAF 12/56 reads (21%) | called by mutect2, pindel, varscan2
- ANKFN1 | c.906A>G p.V302= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV59456912; called by muse, mutect2, varscan2
- APBA2 | c.441G>A p.P147= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as rs375569614; called by muse, mutect2, varscan2
- ARF1 | c.351G>A p.R117= | Silent (SNP) | VAF 33/121 reads (27%) | catalogued as COSV55255733; called by muse, mutect2, varscan2
- ASNS | c.822G>T p.L274= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as COSV51555155; called by muse, mutect2, varscan2
- AUTS2 | c.1047G>A p.Q349= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as COSV61424309, COSV61432694; called by muse, mutect2, varscan2
- B4GALNT4 | c.801C>T p.P267= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs758821621, COSV57324516; called by muse, mutect2, varscan2
- C1S | c.1773T>G p.P591= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV61072053; called by muse, mutect2, varscan2
- DOP1A | c.738A>G p.T246= | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as COSV52715895; called by muse, mutect2, varscan2
- EPPK1 | c.633C>T p.Y211= | Silent (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- HAPLN1 | c.600C>A p.G200= | Silent (SNP) | VAF 28/164 reads (17%) | called by muse, mutect2
- KRTAP10-6 | c.75T>C p.C25= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs1555927007, COSV59975283; called by muse, mutect2, varscan2
- MARK2 | c.1335G>T p.R445= (on ENST00000402010 / NM_001039469.2; = p.R444= on NM_004954.5) | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as COSV59287705; called by muse, mutect2, varscan2
- MFSD3 | c.801C>A p.S267= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV56742674; called by muse, mutect2, varscan2
- MYO15A | c.5370C>T p.P1790= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs1215744215, COSV52763217; called by muse, mutect2, varscan2
- NEB | c.19482T>G p.T6494= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV51449411; called by muse, mutect2, varscan2
- OGFOD3 | c.351C>A p.I117= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV57342830; called by muse, mutect2, varscan2
- OR4P4 | c.429C>A p.I143= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV58923280; called by muse, mutect2, varscan2
- PCDHGA7 | c.465C>T p.S155= | Silent (SNP) | VAF 54/307 reads (18%) | catalogued as COSV54010016; called by muse, mutect2, varscan2
- PEDS1 | c.126G>A p.K42= | Silent (SNP) | VAF 30/131 reads (23%) | catalogued as COSV59015193; called by muse, mutect2, varscan2
- SMG9 | c.1165C>T p.L389= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV54215970; called by muse, mutect2, varscan2
- TMLHE | c.270T>C p.T90= | Silent (SNP) | VAF 73/127 reads (57%) | catalogued as COSV57688959; called by muse, mutect2, varscan2
